Somatic mutation profile of tumor specimen TCGA-CR-7365-01A (aliquot TCGA-CR-7365-01A-11D-2012-08) from TCGA case TCGA-CR-7365, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.5 years (22,101 days).
Specimen TCGA-CR-7365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0da28126-9dc2-467b-96bf-ef8963f8c5a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7365-10A (Blood Derived Normal), aliquot TCGA-CR-7365-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c416bcc0-2ae2-4e12-9a93-092dfe0d04a6

The open-access MAF lists 181 somatic variants for this specimen: 137 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 38, Nonsense Mutation 13, Frame Shift Ins 6, Frame Shift Del 4, 3'Flank 2, Intron 2, Splice Site 2, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 31/42 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1BG | c.341-1G>A p.X114_splice | Splice Site (SNP) | VAF 17/139 reads (12%) | catalogued as COSV99568081; called by muse, mutect2, varscan2
- ABCA12 | c.7738C>G p.Q2580E (on ENST00000272895 / NM_173076.3; = p.Q2262E on NM_015657.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99787781; called by muse, mutect2, varscan2
- ABCA2 | c.3216C>G p.F1072L (on ENST00000614293; = p.F1042L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); catalogued as COSV99686660; called by muse, mutect2, varscan2
- ABCC8 | c.3368G>C p.R1123T | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100216427, COSV100217419; called by muse, mutect2, varscan2
- ACTL6B | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99355378; called by muse, mutect2
- ACVR1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55117033, COSV99717367; called by muse, mutect2, varscan2
- ADAMTS19 | c.2096G>C p.R699T | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50732906, COSV99176182; called by muse, mutect2, varscan2
- AL162417.1 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100923104; called by muse, mutect2, varscan2
- APBA3 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV100349517, COSV57462621; called by muse, mutect2, varscan2
- ARAP1 | c.3562G>C p.E1188Q (on ENST00000393609 / NM_001040118.2; = p.E943Q on NM_015242.4) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV100501416; called by muse, mutect2, varscan2
- ARAP1 | c.3303G>A p.M1101I (on ENST00000393609 / NM_001040118.2; = p.M856I on NM_015242.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61994909; called by muse, mutect2, varscan2
- BAZ2B | c.3116G>C p.R1039T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV99680833; called by muse, mutect2, varscan2
- BBS2 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778179694, COSV99801983; called by muse, mutect2
- BEND2 | c.2371G>C p.D791H | Missense Mutation (SNP) | VAF 70/117 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101192571; called by muse, mutect2, varscan2
- BOD1L1 | c.7469C>A p.S2490* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99238134; called by muse, mutect2, varscan2
- C2CD3 | c.4074G>C p.K1358N | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV100486132; called by muse, mutect2, varscan2
- CARF | c.992G>C p.R331T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100247429; called by muse, mutect2, varscan2
- CASP1 | c.427A>G p.R143G (on ENST00000436863 / NM_033292.4; = p.R122G on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100782676; called by muse, mutect2, varscan2
- CCHCR1 | c.556C>G p.H186D | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100885508; called by muse, mutect2, varscan2
- CDR2L | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs201693484; called by muse, mutect2, varscan2
- CERS1 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV99896701; called by muse, mutect2, varscan2
- CFAP91 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1207533384, COSV56338737; called by muse, mutect2, varscan2
- CNOT6L | c.1496A>T p.N499I (on ENST00000504123 / NM_001286790.2; = p.N494I on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99361184; called by muse, mutect2, varscan2
- CORO1A | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs150186033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPT1C | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV99773163; called by muse, mutect2, varscan2
- CUL7 | c.4293G>C p.K1431N | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.346); catalogued as COSV99537597; called by muse, mutect2, varscan2
- CUL7 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV99537600; called by muse, mutect2, varscan2
- CYP4A11 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100152076; called by muse, mutect2, varscan2
- DNAH11 | c.10171A>G p.I3391V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100176240; called by muse, mutect2, varscan2
- DNAI2 | c.1526T>A p.I509N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100209507; called by muse, mutect2, varscan2
- DST | c.20972G>A p.R6991K (on ENST00000361203 / NM_001374722.1; = p.R4688K on NM_015548.5) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99749706; called by muse, mutect2, varscan2
- EI24 | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV54018798, COSV99628722; called by muse, varscan2
- EIF4B | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100016599; called by muse, mutect2, varscan2
- ELMO2 | c.1859A>G p.E620G | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV99281337; called by muse, mutect2, varscan2
- EPB41L1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99148750; called by muse, mutect2, varscan2
- EPB42 | c.88C>T p.R30C (on ENST00000441366 / NM_001114134.2; = p.R60C on NM_000119.3) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs762673535, COSV55750607; called by muse, mutect2, varscan2
- FOXE3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58632395; called by muse, mutect2
- FSCB | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.278); catalogued as COSV61218205; called by muse, mutect2, varscan2
- GPATCH8 | c.493-1G>C p.X165_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100132392, COSV59196101; called by muse, mutect2, varscan2
- GSDME | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100742208; called by muse, mutect2, varscan2
- H2BC3 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); catalogued as COSV100778234, COSV100778329; called by muse, mutect2, varscan2
- H3C13 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV58943837; called by muse, mutect2, varscan2
- H3C4 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV100587054; called by muse, mutect2, varscan2
- HLTF | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100026662; called by muse, mutect2, varscan2
- HSD17B14 | c.490A>G p.M164V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV99622527; called by muse, mutect2, varscan2
- HUWE1 | c.13087G>T p.A4363S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99470206; called by muse, mutect2, varscan2
- HUWE1 | c.7255G>A p.E2419K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99470209; called by muse, mutect2, varscan2
- IFT140 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757199524, COSV54152205, COSV54153732; called by muse, mutect2, varscan2
- IL16 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767163027, COSV100266707; called by muse, mutect2, varscan2
- IL1B | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99641635; called by muse, mutect2, varscan2
- INTS10 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as COSV101208634; called by muse, mutect2, varscan2
- ITSN1 | c.3517G>C p.E1173Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180430; called by muse, mutect2, varscan2
- KALRN | c.7333G>A p.E2445K (on ENST00000360013 / NM_001024660.4; = p.E748K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.993); catalogued as COSV52249651; called by muse, mutect2, varscan2
- KANSL2 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1307244822, COSV100770800, COSV100770904; called by muse, mutect2, varscan2
- KMT2A | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100627642; called by muse, mutect2, varscan2
- KSR2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs373055394; called by muse, mutect2, varscan2
- LACTB | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486880436, COSV56055347; called by muse, mutect2, varscan2
- LGR5 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV57006770, COSV99877324; called by muse, mutect2, varscan2
- LMNTD1 | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.592); catalogued as COSV99279214; called by muse, mutect2, varscan2
- LOX | c.1243T>A p.S415T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.124); catalogued as COSV99140574; called by muse, mutect2, varscan2
- LRRIQ3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV100598395; called by muse, mutect2, varscan2
- M1AP | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as COSV51206922, COSV99283890; called by muse, mutect2, varscan2
- MAGI2 | c.388C>A p.R130S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831937, COSV62641520, COSV62680550; called by muse, mutect2, varscan2
- MED13 | c.4774C>G p.L1592V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV101180704; called by muse, mutect2, varscan2
- MYH7 | c.2740C>A p.Q914K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as CD1411017, COSV100805584; called by muse, mutect2, varscan2
- NKAP | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 82/137 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV101004146; called by muse, mutect2, varscan2
- NKIRAS2 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100288730; called by muse, mutect2, varscan2
- NOTCH1 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1434047791, COSV53026251; called by muse, mutect2, varscan2
- NSL1 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100875167; called by muse, mutect2, varscan2
- OR2M5 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs749039050, COSV63545850; called by muse, mutect2, varscan2
- OSGEPL1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs761943403, COSV99918257; called by muse, mutect2, varscan2
- PCDH19 | c.2353G>C p.D785H (on ENST00000373034 / NM_001184880.2; = p.D738H on NM_020766.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99718812, COSV99718880; called by muse, mutect2, varscan2
- PCDHB9 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as rs782490536, COSV53377046; called by muse, mutect2, varscan2
- PGAP3 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100328400; called by muse, mutect2, varscan2
- PKD1L2 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100215974; called by muse, mutect2, varscan2
- PLEC | c.9334G>C p.E3112Q (on ENST00000322810 / NM_201380.4; = p.E3002Q on NM_000445.5) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100509252; called by muse, varscan2
- PLEC | c.9273G>C p.K3091N (on ENST00000322810 / NM_201380.4; = p.K2981N on NM_000445.5) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100509255; called by muse, varscan2
- PLEK | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146499837; called by muse, mutect2, varscan2
- PLEKHG1 | c.3451C>T p.Q1151* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as COSV62049088; called by muse, mutect2, varscan2
- PLOD1 | c.1355C>G p.S452* | Nonsense Mutation (SNP) | VAF 54/126 reads (43%) | catalogued as COSV99537497; called by muse, mutect2, varscan2
- POM121L12 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV101374816; called by muse, mutect2, varscan2
- POM121L12 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV68692563, COSV68692636; called by muse, mutect2, varscan2
- POM121L12 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs766537069, COSV68692604; called by muse, mutect2, varscan2
- PPFIA4 | c.2131G>C p.E711Q (on ENST00000447715; = p.E712Q on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99690156; called by muse, mutect2, varscan2
- PRDX6 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100458370; called by muse, mutect2, varscan2
- PRKD3 | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV99305606; called by muse, mutect2, varscan2
- PTPN14 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs772180365, COSV65282278; called by muse, mutect2, varscan2
- RASA1 | c.2558C>G p.S853* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV57200253, COSV57201170; called by muse, mutect2, varscan2
- RNF14 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100641138; called by muse, varscan2
- RTN4 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100462594; called by muse, mutect2
- SDF4 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99767267; called by muse, varscan2
- SDF4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV99767273; called by muse, varscan2
- SELE | c.1826T>G p.I609S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV100324416; called by muse, mutect2, varscan2
- SERAC1 | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs770615349, COSV65598232; called by muse, mutect2, varscan2
- SHC4 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100194083; called by muse, mutect2, varscan2
- SLC37A4 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100421454; called by muse, mutect2, varscan2
- SLC39A4 | c.1510G>A p.D504N (on ENST00000301305 / NM_001374839.1; = p.D479N on NM_017767.3) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554872303, COSV52780435, COSV99433140; called by muse, mutect2, varscan2
- SLC6A5 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV100116246; called by muse, mutect2, varscan2
- SLCO1A2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100261192; called by muse, mutect2, varscan2
- SMAD4 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as COSV61688361; called by muse, mutect2, varscan2
- SPATS1 | c.730C>G p.P244A | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55825336, COSV99913022; called by muse, mutect2, varscan2
- SPEF2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100605954; called by muse, mutect2, varscan2
- SYCP1 | c.6A>C p.E2D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV101050705; called by muse, mutect2, varscan2
- SYNE3 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.131); catalogued as COSV100515546; called by muse, mutect2
- TDRD5 | c.2783C>G p.S928C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99675208; called by muse, mutect2, varscan2
- TENM4 | c.6352G>A p.E2118K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99569686; called by muse, mutect2, varscan2
- TIMELESS | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV57511437; called by muse, mutect2, varscan2
- TNIK | c.3695C>A p.S1232Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99454285; called by muse, mutect2, varscan2
- TRABD2A | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); catalogued as COSV100119557; called by muse, mutect2, varscan2
- TRPA1 | c.2018C>A p.T673K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs780153786, COSV100082819, COSV100084485; called by muse, varscan2
- TRPA1 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100082825, COSV100083748; called by muse, varscan2
- TRPS1 | c.551C>G p.S184* (on ENST00000220888 / NM_001330599.2; = p.S197* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/166 reads (13%) | catalogued as COSV99627659; called by muse, mutect2, varscan2
- TTLL2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99514313; called by muse, mutect2, varscan2
- TTN | c.25015A>G p.K8339E (on ENST00000591111; = p.K7412E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/135 reads (31%) | PolyPhen benign (0.114); catalogued as COSV100589829; called by muse, mutect2, varscan2
- USP6NL | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV99509157; called by muse, mutect2, varscan2
- VCAN | c.5353G>T p.E1785* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV99424300, COSV99425333; called by muse, mutect2, varscan2
- WDTC1 | c.1952T>A p.I651N (on ENST00000319394 / NM_001276252.2; = p.I650N on NM_015023.5) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV100088375; called by muse, mutect2, varscan2
- ZFP28 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.958); catalogued as rs924641892, COSV100019162; called by muse, mutect2, varscan2
- ZNF182 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100526840; called by muse, mutect2, varscan2
- ZNF254 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1381756043, COSV100741457; called by muse, mutect2, varscan2
- ZNF835 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV101606235; called by muse, mutect2, varscan2
- ZUP1 | c.1383G>C p.W461C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884949; called by muse, mutect2, varscan2
- ACO1 | c.2379del p.A794Pfs*20 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | called by mutect2, pindel, varscan2
- DDX43 | c.622dup p.M208Nfs*8 | Frame Shift Ins (INS) | VAF 60/173 reads (35%) | called by mutect2, pindel, varscan2
- FLNA | c.6854_6855del p.F2285* (on ENST00000369850 / NM_001110556.2; = p.F2277* on NM_001456.3) | Frame Shift Del (DEL) | VAF 36/66 reads (55%) | called by mutect2, pindel, varscan2
- GATB | c.1529dup p.A511Gfs*19 | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- LRRC7 | c.2835delinsAA p.N945Kfs*14 (on ENST00000651989 / NM_001370785.2; = p.N912Kfs*14 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | called by pindel, varscan2*
- MLLT6 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTHFD1 | c.1701_1711del p.E568Cfs*24 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- MYH8 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2
- NCAPG | c.2481dup p.D828* | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.1625del p.K542Sfs*89 | Frame Shift Del (DEL) | VAF 42/72 reads (58%) | called by mutect2, pindel, varscan2
- PCDHB10 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.846); called by mutect2, varscan2
- RALGAPA2 | c.488dup p.M163Ifs*18 | Frame Shift Ins (INS) | VAF 21/104 reads (20%) | called by mutect2, pindel, varscan2
- TNRC6A | c.2924dup p.P976Tfs*27 | Frame Shift Ins (INS) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- TUFT1 | c.548_562del p.L183_K187del | In Frame Del (DEL) | VAF 52/234 reads (22%) | called by mutect2, varscan2
- AKAP1 | c.60C>A p.L20= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs867529780, COSV100027684, COSV58471247; called by muse, mutect2, varscan2
- ANKAR | c.1968A>G p.Q656= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99853785; called by muse, mutect2, varscan2
- BMP10 | c.516G>A p.E172= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs1215535242, COSV99770239; called by muse, mutect2, varscan2
- CATSPER2 | c.1488A>G p.R496= (on ENST00000321596 / NM_001282309.3; = p.R498= on NM_172095.4) | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs745821543, COSV100390486; called by muse, mutect2, varscan2
- CBFA2T2 | c.1814G>A p.*605= | Silent (SNP) | VAF 36/140 reads (26%) | catalogued as COSV100656084; called by muse, varscan2
- DDR1 | c.747C>G p.V249= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV100240846; called by muse, mutect2, varscan2
- DDR1 | c.1036C>T p.L346= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV100240849; called by muse, mutect2, varscan2
- DDR1 | c.1389C>G p.L463= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV100240852, COSV100241947; called by muse, mutect2, varscan2
- DDX58 | c.369C>T p.I123= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV101152351, COSV65882978; called by muse, mutect2, varscan2
- DYNC1H1 | c.10947G>C p.L3649= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100794200; called by muse, mutect2
- EGF | c.822A>G p.K274= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99490328; called by muse, mutect2, varscan2
- FLII | c.2277G>A p.L759= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as rs770659287, COSV100374997; called by muse, mutect2, varscan2
- FZD6 | c.2040C>G p.L680= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV100708261; called by muse, mutect2, varscan2
- GCN1 | c.2085G>A p.K695= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV100324503; called by muse, mutect2, varscan2
- GRK4 | c.792C>T p.L264= (on ENST00000398052 / NM_182982.3; = p.L232= on NM_005307.3) | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs867838234, COSV100583779; called by muse, mutect2, varscan2
- HBD | c.267G>C p.L89= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV99496498; called by muse, mutect2, varscan2
- KNTC1 | c.2607C>G p.L869= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV61083257; called by muse, mutect2, varscan2
- LCT | c.960G>T p.L320= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99928320; called by muse, mutect2, varscan2
- LIN9 | c.871C>T p.L291= (on ENST00000366808 / NM_001270410.2; = p.L236= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100066898, COSV100067462; called by muse, mutect2, varscan2
- LMO7 | c.1593A>G p.V531= (on ENST00000357063; = p.V261= on NM_015842.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV100412220; called by muse, mutect2, varscan2
- MAG | c.429C>T p.I143= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV62700149; called by muse, mutect2
- MOCS1 | c.1833C>A p.V611= | Silent (SNP) | VAF 72/172 reads (42%) | catalogued as COSV99224231; called by muse, mutect2, varscan2
- MYO3A | c.1785T>C p.G595= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs746530670, COSV99777712; called by muse, mutect2, varscan2
- NT5C1A | c.489C>G p.L163= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV52493819, COSV52494177; called by muse, mutect2, varscan2
- OR2T6 | c.828C>A p.A276= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100861466; called by muse, mutect2, varscan2
- PLEC | c.8991G>A p.E2997= (on ENST00000322810 / NM_201380.4; = p.E2887= on NM_000445.5) | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV100509261; called by muse, mutect2, varscan2
- PTOV1 | c.924G>A p.P308= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs776730341, COSV99681502; called by muse, mutect2, varscan2
- RIMS4 | c.516C>T p.V172= | Silent (SNP) | VAF 119/496 reads (24%) | catalogued as rs764973471, COSV65720550; called by muse, varscan2
- SOCS7 | c.1911G>A p.Q637= | Silent (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- STX18 | c.466C>A p.R156= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100085993, COSV60376405; called by muse, mutect2, varscan2
- TSPAN10 | c.264G>A p.P88= (on ENST00000574882 / NM_001290212.1; = p.P50= on NM_031945.4) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs373056344; called by muse, mutect2, varscan2
- TSPAN14 | c.300C>T p.L100= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100540111; called by muse, mutect2, varscan2
- UBALD1 | c.84G>C p.A28= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99364195, COSV99364380; called by muse, mutect2, varscan2
- UGT2A1 | c.384C>T p.G128= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs1404918812, COSV99683689; called by muse, mutect2, varscan2
- USP24 | c.3525C>G p.L1175= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs775261308, COSV99598613; called by muse, mutect2, varscan2
- VPS13D | c.11577G>A p.V3859= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs183347742; called by muse, mutect2, varscan2
- ZIK1 | c.1182C>A p.L394= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100277331; called by muse, mutect2, varscan2
- ZZEF1 | c.2937G>A p.L979= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV101067369; called by muse, mutect2, varscan2
- CEP295 | chr11:93731065 G>T | 3'Flank (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.5798T>C | RNA (SNP) | VAF 16/73 reads (22%) | catalogued as rs1229293935, COSV100600890; called by muse, mutect2, varscan2
- MFRP | chr11:119343859 C>A | 5'Flank (SNP) | VAF 41/135 reads (30%) | catalogued as rs969409100, COSV100793288; called by muse, mutect2, varscan2
- MLLT6 | c.819+223G>T | Intron (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- SMIM12 | chr1:34855424 T>C | 3'Flank (SNP) | VAF 10/54 reads (19%) | catalogued as COSV101315042; called by muse, mutect2, varscan2
- USH1C | c.1284+6984T>G | Intron (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99139232; called by muse, mutect2, varscan2
